Somatic mutation profile of tumor specimen TCGA-VP-A87C-01A (aliquot TCGA-VP-A87C-01A-11D-A34U-08) from TCGA case TCGA-VP-A87C, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 67.4 years (24,608 days).
Specimen TCGA-VP-A87C-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0ee93e5b-022c-4ed4-8ce2-094e7fd81633.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VP-A87C-10A (Blood Derived Normal), aliquot TCGA-VP-A87C-10A-01D-A34X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7aa5c225-12c3-485e-aadc-4ce7c56a2225

The open-access MAF lists 20 somatic variants for this specimen: 17 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 14, Silent 3, Frame Shift Del 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SF3B1 | c.2221A>G p.K741E | Missense Mutation (SNP) | VAF 22/70 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV59207072, COSV59211907, COSV59219639; called by muse, mutect2, varscan2
- AP002748.5 | c.1186C>T p.R396C | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); catalogued as rs759882869, COSV59148455; called by muse, mutect2, varscan2
- ARNTL2 | c.1120C>G p.R374G | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs543030579, COSV53824318, COSV99667360; called by muse, mutect2, varscan2
- C2orf16 | c.3098C>T p.S1033F | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.105); catalogued as COSV100820606; called by muse, mutect2, varscan2
- CD5L | c.418C>A p.L140M | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100940962, COSV63821442; called by muse, mutect2, varscan2
- CMYA5 | c.2548G>T p.V850F | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.314); catalogued as COSV101483715; called by muse, mutect2
- HOOK2 | c.1771G>A p.A591T | Missense Mutation (SNP) | VAF 7/123 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.321); catalogued as COSV99317267; called by muse, mutect2
- INPPL1 | c.209G>C p.R70P | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1211223270, COSV53353022, COSV99995692; called by muse, mutect2, varscan2
- KCNH7 | c.2119G>A p.A707T | Missense Mutation (SNP) | VAF 28/142 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.049); catalogued as rs1189248654, COSV100033468; called by muse, mutect2, varscan2
- KTN1 | c.248A>G p.D83G | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs1249407277, COSV101254904; called by muse, mutect2, varscan2
- OR56A3 | c.842A>G p.N281S | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as rs759544703, COSV100289954; called by muse, mutect2, varscan2
- PLOD3 | c.293A>G p.E98G | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as COSV99777745; called by muse, mutect2, varscan2
- RAD54L2 | c.1933G>A p.V645M | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.752); catalogued as rs768697587, COSV99620494; called by muse, mutect2, varscan2
- TELO2 | c.2165T>C p.L722P | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99247925; called by muse, mutect2
- C4orf51 | c.132del p.V45* | Frame Shift Del (DEL) | VAF 17/112 reads (15%) | called by mutect2, pindel, varscan2
- CCNI | c.778del p.Y260Mfs*11 | Frame Shift Del (DEL) | VAF 7/60 reads (12%) | called by mutect2, pindel, varscan2
- ILF3 | c.3+2dup p.X1_splice | Splice Site (INS) | VAF 8/58 reads (14%) | called by mutect2, pindel, varscan2
- ADAMTS3 | c.975A>T p.P325= | Silent (SNP) | VAF 14/64 reads (22%) | catalogued as COSV99709941; called by muse, mutect2, varscan2
- GPR142 | c.81T>C p.G27= | Silent (SNP) | VAF 12/53 reads (23%) | catalogued as COSV100170639; called by muse, mutect2, varscan2
- OTOGL | c.1335C>T p.C445= (on ENST00000547103; = p.C436= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as rs776984171, COSV72005618; called by muse, mutect2, varscan2
